Surgical pathology report (de-identified scan), TCGA case TCGA-QU-A6IO, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site Harvard Beth Israel, specimen TCGA-QU-A6IO-01A (Primary Tumor).

[page 1 of 3]
Pathology Examination

Name	Birthdate	Age	Sex	Pathology #
[REDACTED]	[REDACTED]		Male	

Report to:

Gross Description by:

SPECIMEN SUBMITTED: RT & LT OBTURATOR NODES/PROSTATE.

Procedure date Tissue received Report Date Diagnosed by

Previous biopsies: PROSTATE BX'S.
SKIN SCALP**DIAGNOSIS:**

A. (Right obturator lymph node, A-C):

Lymph node with no malignancy identified.

B. (Left obturator lymph node D-F):

Lymph node with no malignancy identified, see note.

C. (Prostate, G-X):

Adenocarcinoma, see synoptic report.

Note: Although multiple lymph node profiles present on the slides of the left obturator lymph node specimen, the number of individual nodes represented by these profiles is not clear.

Prostate Gland: Radical prostatectomy Synopsis**MICROSCOPIC****Histologic Type:** Adenocarcinoma.**Histologic Grade -- Gleason Pattern****Primary pattern:** Grade 3.**Secondary pattern:** Grade 3.**Total Gleason Score:** 6.**Tumor quantitation**

CCCF ICD-O-3
Adenocarcinoma, acinar
path 8/40/3
Adenocarcinoma NOS
8/40/3
Site Prostate NOS
C61.9

JD 6/17/13

[page 2 of 3]
	# Positive Slides	Total Slides
Left	3	5
Left apex	2	3
Right	3	5
Right apex	3	3

EXTENT OF INVASION

Primary Tumor: pT2c: Bilateral disease.

Regional Lymph Nodes: pN0: No regional lymph node metastasis.

Lymph Nodes

Number examined: see Comments

Number involved: see Comments

Margins

Tumor extends to the inked capsular margin of the left lobe (slides U and V). The bladder margin and inked apical margins are free of tumor.

Extraprostatic extension: Absent.

Seminal vesicle invasion (invasion of muscular wall required): Absent.

Perineural invasion: Present.

Comments: There is one right obturator lymph node and that shows no evidence of malignancy. Sections of the left obturator lymph node specimen reveal multiple lymph node profiles, but is not clear how many nodes are represented by these profiles. However all of these sections are free of tumor.

Clinical: Carcinoma of prostate on needle biopsy.

Gross:

The specimen is received fresh in three parts, all labeled [REDACTED] and the medical record number.

Part 1 is additionally labeled "right obturator lymph node" and consists of a 3.5 x 3.0 x 1.0 cm fatty tissue excision weighing 4 grams. The specimen is sectioned to reveal 1.0 x 1.0 x 1.0 possible lymph node with a tan white granular cut surface. The remainder of the specimen is unremarkable fatty tissue. The specimen is represented as follows: A = large node bisected, B-C = adjacent soft tissue.

Part 2 is additionally labeled "left obturator lymph node" and consists of a 4.3 x 2.5 x 1.0 cm fatty tissue excision, weighing 4 grams. The specimen is represented as follows: D = one large possible node bisected, E-F = soft tissue.

Part 3 is additionally labeled "prostate" and consists of a 59 gram prostate specimen measuring 5.5 x 5.2 x 4.5 cm with a right seminal vesicle measuring 2.5 x 2.0 x 1.0 cm and a left seminal vesicle measuring 2.5 x 2.0 x 1.0 cm. The specimen has been oriented by the surgeon with a stitch

[page 3 of 3]
in the right seminal vesicle. The right vas deferens is 3 cm in length with an average diameter of 0.4 cm, the left vas deferens is 2.2 cm in length with an average diameter of 0.4 cm. The specimen is inked with the right side in black and the left side in blue and is serially sectioned from apex to the base. There is diffuse nodularity in the apex measuring 2 cm in greatest diameter. There is additionally in the posterior apex a firm rubbery nodule measuring approximately 0.8 cm in largest dimension. In the right mid apex there is a firm white nodule measuring 0.4 cm in greatest dimension. In the left mid prostate there is a palpable nodule measuring approximately 0.2 cm. There is additionally some diffuse nodularity posteriorly in the mid base to base region. The specimen is represented as follows: G = right seminal vesicle and vas deferens, H = left seminal vesicle and vas deferens, I = shaved left base prostate, J = shaved right base of prostate, K-M = left apex, N-P = right apex, Q = left and right posterior apex, R = right posterior mid apex, S = left posterior mid prostate, T = left posterior mid base, U = right posterior mid base, V = left base, W = left and right base, X = right mid prostate.

By his/her signature above, the senior physician certifies that he/she personally conducted a gross and/or microscopic examination of the described specimens(s) and rendered or confirmed the diagnosis(es) related thereto.

Immunohistochemistry test(s), if applicable, were developed and their performance characteristics were determined by

They have not been cleared or approved by the U.S. Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. These tests are used for clinical purposes. They should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA - 88) as qualified to perform high complexity clinical laboratory testing.

Criteria:	fw 6/11/13	Yes	No

Source: NCI Genomic Data Commons file 30f74fc4-3be3-4c40-8d77-685a3d296c6f (TCGA-QU-A6IO.6450E3BE-55E8-4A6C-AA40-86B74F30458B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).